Somatic mutation profile of tumor specimen C3L-01313-03 (aliquot CPT0086820009) from CPTAC case C3L-01313, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 63.7 years (23,275 days).
Specimen C3L-01313-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40e40384-9a31-4fc9-a933-62e9a5b5f59a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01313-31 (Blood Derived Normal), aliquot CPT0087430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55249877-19e8-4a6d-8b9c-d10174d66abb

The open-access MAF lists 127 somatic variants for this specimen: 80 protein-altering or splice-affecting, 26 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 26, Intron 10, Frame Shift Del 10, 3'UTR 4, RNA 3, Nonsense Mutation 3, In Frame Del 2, 5'Flank 2, Frame Shift Ins 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 135/281 reads (48%) | catalogued as rs5030829, CM156382, CM941369, COSV56543353, COSV56543426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.4316T>C p.L1439P | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV54051479; called by muse, mutect2, varscan2
- FOXN1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs907070119; called by muse, mutect2, varscan2
- GCFC2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV58081321; called by muse, mutect2, varscan2
- HAUS4 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs753080897; called by muse, mutect2, varscan2
- KCNA4 | c.404_412dup p.E135_E137dup | In Frame Ins (INS) | VAF 32/168 reads (19%) | catalogued as rs752488769; called by mutect2, varscan2
- PIAS3 | c.851C>G p.T284S | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.16); catalogued as rs200283710; called by muse, mutect2, varscan2
- PRSS33 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs748539512; called by muse, mutect2, varscan2
- RBM34 | c.1206del p.F402Lfs*51 | Frame Shift Del (DEL) | VAF 53/275 reads (19%) | catalogued as rs773410897; called by mutect2, pindel, varscan2
- RELN | c.2807G>A p.C936Y | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100633613; called by muse, mutect2, varscan2
- RYR2 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.974); catalogued as COSV63694226; called by muse, mutect2, varscan2
- UBAC1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs771410214; called by muse, varscan2
- ZYG11B | c.1129T>A p.L377M | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53755692; called by muse, mutect2, varscan2
- A4GNT | c.667_668dup p.Q223Hfs*6 | Frame Shift Ins (INS) | VAF 94/274 reads (34%) | called by mutect2, pindel, varscan2
- ACSL1 | c.1322C>A p.T441N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ACSS1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCK5 | c.1016_1025del p.I339Sfs*71 | Frame Shift Del (DEL) | VAF 173/424 reads (41%) | called by mutect2, pindel, varscan2
- AFMID | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALB | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ANAPC4 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2
- ASTN1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BAP1 | c.154T>G p.W52G | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BIRC6 | c.6701_6703del p.Q2234del | In Frame Del (DEL) | VAF 21/104 reads (20%) | called by pindel, varscan2
- BRD2 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CASP9 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEP135 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP251 | c.1261T>A p.Y421N | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CFHR3 | c.380T>A p.V127D | Missense Mutation (SNP) | VAF 130/772 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLSTN3 | c.1216G>C p.G406R | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CNTN2 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL5A3 | c.4703C>T p.A1568V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYSF | c.2777G>C p.W926S | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERBB4 | c.2729T>G p.I910R | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- FTCD | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 148/499 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- GLCCI1 | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPS2 | c.514del p.A172Qfs*173 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- GTF2H1 | c.418del p.E140Rfs*8 | Frame Shift Del (DEL) | VAF 43/234 reads (18%) | called by mutect2, pindel, varscan2
- IFT140 | c.3019dup p.T1007Nfs*113 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.3809T>C p.L1270P | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KBTBD11 | c.1514T>G p.F505C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.992T>A p.I331K | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MEN1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MIDEAS | c.2314_2337del p.L772_S779del | In Frame Del (DEL) | VAF 35/112 reads (31%) | called by mutect2, pindel
- MROH7 | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 34/151 reads (23%) | called by muse, mutect2, varscan2
- NAPSA | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLE1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D18 | c.161_162delinsA p.P54Qfs*31 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by pindel, varscan2*
- OSBPL8 | c.1714T>C p.Y572H | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PARD3 | c.1155C>A p.D385E | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDHGB6 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 102/489 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHTF1 | c.1446del p.V483Sfs*5 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | called by mutect2, pindel, varscan2
- PRICKLE1 | c.2381A>G p.Y794C | Missense Mutation (SNP) | VAF 162/377 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PSMD11 | c.193+2dup p.X65_splice | Splice Site (INS) | VAF 38/147 reads (26%) | called by mutect2, pindel, varscan2
- PTPRF | c.3988C>A p.P1330T | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RNFT1 | c.585del p.L196* | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- RO60 | c.871_881del p.N291* | Frame Shift Del (DEL) | VAF 50/179 reads (28%) | called by mutect2, pindel, varscan2
- RPGR | c.29-2A>G p.X10_splice | Splice Site (SNP) | VAF 83/127 reads (65%) | called by muse, mutect2, varscan2
- RPL24 | c.5+3A>G | Splice Region (SNP) | VAF 92/380 reads (24%) | called by muse, mutect2, varscan2
- RPP40 | c.208A>T p.K70* | Nonsense Mutation (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- SAFB | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SF3A1 | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SF3A2 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SIRT1 | c.1603del p.S535Qfs*17 | Frame Shift Del (DEL) | VAF 80/347 reads (23%) | called by mutect2, pindel, varscan2
- STON2 | c.2813C>T p.P938L (on ENST00000649389 / NM_001366849.2; = p.P881L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEA2 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TEAD1 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 134/522 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TNXB | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOMM70 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPO | c.2114C>A p.P705H | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ULK2 | c.704G>C p.S235T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- USP15 | c.2362T>G p.L788V (on ENST00000280377 / NM_001351159.2; = p.L759V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAM1 | c.832T>A p.L278I | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- WDR18 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- YARS1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 106/424 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBED4 | c.56A>C p.K19T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZMYM1 | c.887T>C p.L296S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZMYM1 | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF184 | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF292 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF705D | c.826_835del p.I276Lfs*? (on ENST00000400078; = p.I276Lfs*62 on NM_001039615.3) | Frame Shift Del (DEL) | VAF 91/303 reads (30%) | called by mutect2, pindel, varscan2
- ACAD10 | c.231G>A p.K77= | Silent (SNP) | VAF 147/297 reads (49%) | called by muse, mutect2, varscan2
- AKT1 | c.1272C>A p.P424= | Silent (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.4002T>C p.S1334= | Silent (SNP) | VAF 98/332 reads (30%) | called by muse, mutect2, varscan2
- CLNK | c.762G>A p.V254= | Silent (SNP) | VAF 9/230 reads (4%) | called by muse, mutect2
- CYP2U1 | c.744C>T p.F248= | Silent (SNP) | VAF 109/336 reads (32%) | called by muse, mutect2, varscan2
- CYP4F11 | c.990T>C p.H330= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- DSG1 | c.2505C>A p.V835= | Silent (SNP) | VAF 101/276 reads (37%) | catalogued as COSV57136190; called by muse, mutect2, varscan2
- INTS6 | c.93G>T p.A31= | Silent (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- IRAK2 | c.1788T>C p.I596= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- KLF12 | c.810A>G p.V270= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1173939212; called by muse, mutect2, varscan2
- LCN6 | c.432C>T p.S144= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs774261451; called by muse, mutect2, varscan2
- MYO9A | c.3123T>C p.H1041= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs111920017; called by muse, mutect2, varscan2
- NCOA6 | c.1087T>C p.L363= | Silent (SNP) | VAF 55/159 reads (35%) | called by muse, mutect2, varscan2
- NOS2 | c.459C>T p.S153= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- NUF2 | c.372T>C p.I124= | Silent (SNP) | VAF 77/333 reads (23%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7086G>A p.L2362= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- PLA2G5 | c.372C>T p.S124= | Silent (SNP) | VAF 72/252 reads (29%) | catalogued as rs1189901330; called by muse, mutect2, varscan2
- PNPLA3 | c.33C>A p.S11= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, varscan2
- PPP1R1C | c.303T>C p.N101= | Silent (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- PPWD1 | c.1593T>C p.H531= | Silent (SNP) | VAF 37/198 reads (19%) | called by muse, mutect2, varscan2
- PRKAA1 | c.345T>C p.Y115= | Silent (SNP) | VAF 53/214 reads (25%) | called by muse, mutect2, varscan2
- RBM27 | c.3117T>C p.D1039= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- SSH1 | c.2251C>T p.L751= | Silent (SNP) | VAF 89/380 reads (23%) | called by muse, mutect2, varscan2
- TPO | c.2112G>C p.V704= | Silent (SNP) | VAF 99/468 reads (21%) | catalogued as COSV61104594; called by muse, mutect2
- TRPM3 | c.1413C>A p.I471= (on ENST00000357533 / NM_001366142.2; = p.I316= on NM_020952.6) | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as COSV62594553; called by muse, mutect2, varscan2
- VEPH1 | c.1887T>A p.P629= | Silent (SNP) | VAF 55/169 reads (33%) | called by muse, mutect2, varscan2
- ACSF2 | c.128+588A>G | Intron (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*365C>G | 3'UTR (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504229 T>C | 5'Flank (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- C5 | c.4762+10C>T | Intron (SNP) | VAF 11/310 reads (4%) | called by muse, mutect2
- CD37 | c.142+16del | Intron (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- DOCK8 | c.-11G>A | 5'UTR (SNP) | VAF 29/179 reads (16%) | catalogued as rs533265595; called by muse, mutect2, varscan2
- EFHC1 | c.*2266del | 3'UTR (DEL) | VAF 58/194 reads (30%) | called by mutect2, pindel, varscan2
- ERBIN | c.3634-3257T>C | Intron (SNP) | VAF 79/176 reads (45%) | called by muse, mutect2, varscan2
- F12 | c.1531+10A>G | Intron (SNP) | VAF 61/457 reads (13%) | called by muse, mutect2, varscan2
- LINC00115 | n.537C>A | RNA (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- LPL | c.250-20G>A | Intron (SNP) | VAF 92/211 reads (44%) | called by muse, mutect2, varscan2
- MTHFR | c.*45T>G | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, varscan2
- NEIL1 | c.-23+507C>G | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs1385546648; called by muse, mutect2, varscan2
- RBM44 | chr2:237813654 C>T | 5'Flank (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.43+65C>A | Intron (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- SNORD116-3 | n.67T>C | RNA (SNP) | VAF 66/275 reads (24%) | called by muse, mutect2, varscan2
- SPPL2B | c.956+326T>C | Intron (SNP) | VAF 61/198 reads (31%) | called by muse, mutect2, varscan2
- USP48 | c.1964-31T>G | Intron (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2
- VAMP1 | c.*431A>T | 3'UTR (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221464 A>T | 3'Flank (SNP) | VAF 78/263 reads (30%) | called by muse, mutect2, varscan2
- ZNF658B | n.2092T>A | RNA (SNP) | VAF 56/314 reads (18%) | called by mutect2, varscan2
